Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5FZ, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5FZ-01A (Primary Tumor).

[page 1 of 2]
ICD0-3
Carcinoma, Squamous cell,
papillary 8052/3
Site: R Lung, upper lobe
(C34.1)
JAS 2/7/13

Histopathology Report

LEFT UPPER LOBECTOMY

One request form states left upper lobectomy. Lymph nodes Nos. 5 and 6. However, a second request form has been sent which states right upper lobectomy, lymph node No. 10.

The patient details on both request forms are correct.

Three specimens have been received for this patient. Specimen 1 is labelled right upper lobe. Specimen 2 is labelled lymph node No. 5. Specimen 3 is labelled hilar lymph node.

The above discrepancies have been noted.

Three specimens submitted:

1: RIGHT UPPER LOBECTOMY

Macroscopy:

The specimen consists of a right upper lobectomy specimen which measures 150 x 130 x 95 mm post inflation. The bronchial resection margin measures 20 x 8 mm. Some peribronchial lymph nodes are identified. In addition, some adjacent large hilar lymph nodes are also seen. There is a longitudinal parenchymal stapled surgical resection margin present which measures up to 18 mm in length. Multiple fibrous adhesions are present over the pleural surface of the lungs. On sectioning through the pulmonary parenchyma there is a cavitating white circumscribed tumour present which measures up to 45 mm in maximum dimension and abuts the apical, lateral and hilar pleural surfaces of the lung. The surrounding lung parenchyma shows evidence of emphysema. The bronchial resection margin and stapled parenchymal resection margin show no evidence of malignancy. The stapled parenchymal resection margin is at least 15 mm away from the tumour. [Section taken through the bronchial resection margin, 1A; peribronchial lymph nodes, 1B-1C; hilar lymph nodes, 1D-1H; section taken through the tumour where it abuts the apical pleural surface, 1I; sections taken through the tumour where it involves the hilar pleural surface, 1J-1L; sections taken through the tumour where it abuts the lateral pleural surface, 1M-1O; section taken through the centre of the tumour, 1P; section taken through the uninvolved pulmonary parenchyma, 1Q; sections taken through the inked parenchymal stapled resection margin, 1R-1S].

Microscopy:

Sections show a moderately differentiated squamous cell carcinoma. The tumour has a prominent papillary configuration. It invades into the pleura laterally and is associated with surface adhesions in this region. No tumour is identified on the surface though. Tumour also invades into the mediastinal/hilar fat focally. The tumour in this region has a pushing margin and abuts a hilar lymph node which shows no definite involvement. There is no evidence of blood vessel, lymphatic or perineural permeation. No lymph node involvement is identified. The bronchial resection margin shows chronic

[page 2 of 2]
inflammation but no malignancy. The adjacent lung shows similar chronic inflammation around bronchi and bronchioles together with emphysema.

2: NO. 5 LYMPH NODE

Macroscopy:

The specimen consists of a lymph node which measures 15 x 8 x 8 mm. [Bisected and BIT, 2A-2B].

Microscopy:

Sections of the lymph node show reactive changes only. There is no evidence of malignancy.

3: HILAR LYMPH NODE

Macroscopy:

The specimen consists of a fragmented lymph node which measures 18 x 15 x 12 mm. [Trisected and BIT, 3A].

Microscopy:

Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

Summary:

Upper lobe lung and lymph nodes:

- 1: Moderately differentiated papillary squamous cell carcinoma; 45 mm in maximal dimension.
- 2: No blood vessel, lymphatic or perineural invasion present.
- 3: Pleural invasion and focal involvement of mediastinal fat identified; clear of bronchial margin.
- 4: No lymph node metastases.
- 5: T4N0MX

T-28000 M-80703 P1-03000

Reported by
Anatomical Pathologist

Copies:

	ANATOMICAL PATHOLOGY
	Report generated:

Source: NCI Genomic Data Commons file b00eb398-4c96-43b8-b355-e46bf1833585 (TCGA-77-A5FZ.7297BF03-518D-4643-8DA9-D8B360D9D3E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).